Gene-level copy-number profile of tumor specimen CUPP-B38K-TTM1-A from CCG case CUPP-B38K, project CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, metastatic, NOS; Tissue or organ of origin: Unknown primary site; AJCC pathologic stage: Stage III; Age at diagnosis: 63.4 years (23,142 days).
Specimen CUPP-B38K-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6417f2a4-9ebd-46f4-ab39-40cda1648e3a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator CUPP-B38K-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,252 have no estimate.
https://portal.gdc.cancer.gov/files/35615095-1fa5-4dff-954b-f9750df0866c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 57; copy number 1: 18,468; copy number 2: 36,534; copy number 3: 2,496; copy number 4: 474; copy number 5: 218; copy number 6: 54; copy number 7: 9; copy number 8: 23; copy number 9: 15; copy number 10: 4; copy number 13: 11; copy number 15: 5; copy number 50: 3.

Homozygous deletions (total copy number 0; autosomes only): 57 genes in 30 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:3,069,168–3,438,621, 7 genes (within-gene range 0–1): PRDM16, MIR4251, AL008733.1, AL512383.1, AL590438.1, AL354743.2, AL354743.1.
- chr1:3,746,460–3,771,645, 1 gene (within-gene range 0–1): CCDC27.
- chr1:7,693,124–7,700,970, 3 genes (within-gene range 0–1): AL359881.3, AL359881.2, AL359881.1.
- chr1:37,330,852–37,330,996, 1 gene: RPS29P6.
- chr1:162,979,551–162,979,793, 1 gene: AL392003.1.
- chr1:166,603,916–166,631,400, 1 gene: FMO9P.
- chr5:150,166,778–150,184,558, 1 gene: CDX1.
- chr6:40,271,566–40,276,237, 1 gene: AL139275.2.
- chr6:166,409,364–166,906,451, 6 genes (within-gene range 0–1): RPS6KA2, RPS6KA2-IT1, MIR1913, RAMACL, AL023775.2, AL023775.1.
- chr6:168,716,606–168,723,495, 1 gene: AL136099.1.
- chr7:37,032–37,477, 1 gene: AC215522.1.
- chr7:153,449,429–153,449,875, 1 gene: PAXBP1P1.
- chr7:154,092,201–154,096,043, 1 gene (within-gene range 0–1): AC006019.2.
- chr7:154,838,388–154,865,483, 1 gene (within-gene range 0–1): AC073336.1.
- chr7:155,070,324–155,106,651, 4 genes (within-gene range 0–1): HTR5A, AC093726.3, AC092628.2, AC092628.1.
- chr7:155,222,903–155,223,851, 1 gene: AC099552.4.
- chr7:157,574,336–157,618,765, 2 genes (within-gene range 0–1): MIR153-2, AC005481.1.
- chr7:158,532,718–158,532,813, 1 gene (within-gene range 0–1): MIR595.
- chr7:158,730,995–158,830,253, 1 gene: ESYT2.
- chr8:125,430,358–125,438,403, 1 gene: TRIB1.
- chr10:123,356,450–123,537,767, 2 genes: LINC02641, AL160290.1.
- chr12:132,277,349–132,284,606, 3 genes (within-gene range 0–2): AC148477.2, AC148477.5, AC148477.4.
- chr12:132,565,071–132,593,698, 3 genes (within-gene range 0–1): AC131212.2, MIR6763, AC131212.1.
- chr16:991,151–1,000,926, 1 gene: AC009041.1.
- chr16:70,173,322–70,187,361, 1 gene: CLEC18C.
- chr17:20,554,137–20,554,380, 1 gene: AC015818.1.
- chr17:28,204,616–28,223,735, 2 genes: AC061975.8, AC061975.7.
- chr17:33,099,969–33,131,743, 2 genes (within-gene range 0–1): AC008133.2, AC008133.1.
- chr19:43,192,702–43,269,530, 3 genes: PSG4, CEACAMP10, PSG9.
- chr21:44,172,169–44,194,338, 2 genes: AP001056.2, AP001056.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 342 genes in 32 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:150,211,632–150,353,233, 10 genes, copy number 5: RN7SL480P, ANP32E, RNU2-17P, AC242988.1, CA14, APH1A, C1orf54, CIART, MRPS21, PRPF3.
- chr1:150,487,364–150,518,032, 4 genes, copy number 5: TARS2, MIR6878, ECM1, FALEC.
- chr1:151,008,420–151,146,664, 10 genes, copy number 5: PRUNE1, RNU6-884P, BNIPL, C1orf56, CDC42SE1, MLLT11, GABPB2, RPS29P29, AL592424.1, SEMA6C.
- chr1:156,192,063–156,282,825, 7 genes, copy number 5: AL135927.1, SLC25A44, PMF1-BGLAP, PMF1, BGLAP, PAQR6, SMG5.
- chr2:25,994,794–25,995,081, 1 gene, copy number 6: UQCRHP2.
- chr2:231,706,895–231,713,551, 1 gene, copy number 5 (within-gene range 3–5): PTMA.
- chr2:231,713,314–231,713,398, 1 gene, copy number 5: MIR1244-1.
- chr4:188,091,273–189,475,192, 21 genes, copy number 5–7: TRIML2, AC108073.2, RNU6-173P, TRIML1, AC138781.1, LINC02434, AC093789.1, ICE2P1, LINC01060, AC093909.3, AC093909.5, RNU7-192P, AC093909.1, AC093909.6, AC093909.2, LINC02508, AC093909.4, AC122138.1, AC107391.1, AC105924.1, HSP90AA4P.
- chr4:189,764,391–190,092,279, 23 genes, copy number 5 (within-gene range 4–5): FRG1-DT, LINC01596, FRG1, MLLT10P2, AF146191.2, TUBB7P, RNA5SP174, RNA5SP175, DUX4L9, FRG2, RARRES2P4, AGGF1P1, CLUHP4, DBET, U85056.1, DUX4L8, DUX4L7, DUX4L6, DUX4L5, DUX4L4, DUX4L1, DUX4L3, DUX4L2.
- chr7:74,082,933–74,122,525, 1 gene, copy number 5: LIMK1.
- chr8:97,358,265–98,036,724, 10 genes, copy number 5–7 (within-gene range 4–7): SNORD3H, AP002982.1, MTDH, Y_RNA, LAPTM4B, AP003357.1, AP002906.1, SUMO2P18, RPS23P1, MATN2.
- chr8:106,759,483–106,770,244, 1 gene, copy number 5: ABRA.
- chr8:107,857,589–108,489,196, 9 genes, copy number 5: AC025508.1, RNA5SP275, RSPO2, NRBF2P4, AURKBP1, EIF3E, AC087620.1, RPS17P14, EMC2.
- chr8:109,777,912–109,899,762, 2 genes, copy number 5: AC023245.2, AC023245.1.
- chr8:110,105,076–110,105,964, 1 gene, copy number 5: RPSAP48.
- chr8:111,376,639–111,757,710, 2 genes, copy number 5 (within-gene range 4–5): LINC02237, SERPINA15P.
- chr8:123,416,726–123,470,028, 2 genes, copy number 5: NTAQ1, U4.
- chr8:126,474,189–130,017,129, 46 genes, copy number 5–15 (within-gene range 5–16): AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, CASC11, MYC, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, MIR1207, MIR1208, RN7SKP226, LINC00824, CCDC26, AC103833.2, AC103833.1, RN7SKP206, AC011257.1, MIR3686, MTRF1LP2, GSDMC, AC022973.5, CYRIB, AC022973.2, AC022973.1, AC022973.4, AC022973.3, AC131568.1, RNU7-181P, MIR5194.
- chr8:139,096,305–141,195,808, 24 genes, copy number 6–9: AC027541.1, AC100807.1, AC100807.2, AC087354.1, AC090093.1, KCNK9, TRAPPC9, AC021744.1, C8orf17, AC040978.1, PEG13, AC107375.1, CHRAC1, AGO2, AC067931.1, AC067931.2, ERICD, PTK2, MIR151A, AC105235.1, RNA5SP278, AC100860.1, DENND3, AC040970.1.
- chr11:62,728,069–62,766,710, 3 genes, copy number 5: TTC9C, ZBTB3, POLR2G.
- chr11:117,117,794–117,119,181, 1 gene, copy number 5: AP000936.2.
- chr12:56,158,346–56,237,846, 6 genes, copy number 5 (within-gene range 3–5): MYL6, SMARCC2, AC073896.4, RNF41, NABP2, SLC39A5.
- chr12:118,063,593–118,145,584, 3 genes, copy number 5: VSIG10, AC131238.1, PEBP1.
- chr12:120,594,015–122,896,127, 85 genes, copy number 5–6 (broad region; genes not listed).
- chr12:122,983,480–123,150,015, 1 gene, copy number 5 (within-gene range 4–5): PITPNM2.
- chr12:123,081,384–123,935,720, 35 genes, copy number 5–7 (within-gene range 2–7): PITPNM2-AS1, AC026362.2, MPHOSPH9, AC073857.1, C12orf65, CDK2AP1, AC068768.1, RNA5SP375, SBNO1, Y_RNA, SBNO1-AS1, MIR8072, KMT5A, RILPL2, COPS5P2, SNRNP35, RILPL1, AC145423.1, AC145423.2, MIR3908, TMED2-DT, TMED2, DDX55, SNORA9B, EIF2B1, GTF2H3, AC117503.3, AC117503.2, TCTN2, AC117503.1, ATP6V0A2, AC117503.5, RPL27P12, AC117503.4, DNAH10.
- chr15:21,405,401–21,877,735, 26 genes, copy number 5–50: POTEB3, MIR3118-3, U6, NF1P9, MIR5701-2, AC183088.4, AC183088.2, AC183088.1, LINC02203, AC183088.3, AC135068.6, AC135068.2, AC135068.12, AC135068.11, AC135068.1, AC135068.4, AC135068.5, AC135068.8, AC135068.7, AC135068.9, AC135068.10, AC135068.3, AC134981.1, MIR3118-4, POTEB, RNU6-631P.
- chr15:22,178,107–22,185,402, 2 genes, copy number 5: IGHV1OR15-3, IGHV4OR15-8.
- chr16:30,114,105–30,123,506, 1 gene, copy number 5: MAPK3.
- chr16:30,336,400–30,343,336, 1 gene, copy number 5: AC106782.4.
- chr20:34,347,671–34,347,785, 1 gene, copy number 5: AL356299.1.
- chr21:44,133,610–44,210,114, 1 gene, copy number 5 (within-gene range 0–5): GATD3A.

Autosomal genes at a single copy (total copy number 1): 18,465. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
